Gene-level copy-number profile of tumor specimen TCGA-5T-A9QA-01A from TCGA case TCGA-5T-A9QA, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.1 years (19,031 days).
Specimen TCGA-5T-A9QA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.74d626f8-5b32-4cc9-b86a-2ddd8fd46651.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-5T-A9QA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e0e9246-112f-46d6-85da-f0b78f303dea

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 921; copy number 2: 12,938; copy number 3: 30,929; copy number 4: 7,645; copy number 5: 4,579; copy number 6: 644; copy number 7: 1,655; copy number 8: 41; copy number 9: 30; copy number 10: 148; copy number 13: 111; copy number 14: 123; copy number 18: 53.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-5T-A9QA-01A-11D-A41E-01): tumor purity 0.83, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,161 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,614,333–120,127,074, 41 genes, copy number 8: PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P.
- chr1:161,505,430–171,251,857, 212 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:176,857,302–178,561,029, 20 genes, copy number 7: ASTN1, MIR488, BRINP2, LINC01645, AL136114.1, LINC01741, SEC16B, CRYZL2P-SEC16B, CRYZL2P, AL359075.1, RASAL2-AS1, RASAL2, AL160281.1, AL365357.1, CLEC20A, Metazoa_SRP, AL513013.1, TEX35, C1orf220, RNA5SP69.
- chr1:180,434,800–248,919,946, 1,388 genes, copy number 7 (broad region; genes not listed).
- chr6:65,302,522–68,635,161, 22 genes, copy number 7–10: AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1.
- chr8:31,639,222–32,855,666, 1 gene, copy number 10 (within-gene range 2–10): NRG1.
- chr8:32,192,028–43,674,591, 229 genes, copy number 10–14 (broad region; genes not listed).
- chr11:69,294,151–71,863,658, 77 genes, copy number 14–18 (broad region; genes not listed).
- chr11:71,878,453–71,884,561, 1 gene, copy number 18: DEFB131B.
- chr11:74,235,801–79,612,300, 147 genes, copy number 7–13 (broad region; genes not listed).
- chr20:19,000,709–20,738,731, 23 genes, copy number 7: AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P.

Autosomal genes at a single copy (total copy number 1): 921. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
